Surgical pathology report (de-identified scan), TCGA case TCGA-YC-A89H, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Spectrum Health, specimen TCGA-YC-A89H-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

year-old female, bladder cancer, not previously treated

ICD0-3
Carcinoma, urothelial NOS
8120/3
Site Bladder NOS
C67.9
Jan 11/22/13

Research Dx

Invasive high grade urothelial carcinoma.

CASE SUMMARY FOR URINARY BLADDER BIOPSY AND TRANSURETHRAL RESECTION OF
BLADDER TUMOR (TURBT):

Histologic type: Urothelial carcinoma with squamous differentiation

50% squamous, per TSS.
PCR

Associated epithelial lesions: None identified

Histologic grade (WHO/ISUP): High grade

Tumor configuration: Indeterminate

Adequacy of material for determining muscularis propria invasion: Muscularis propria identified

Lymphovascular invasion: Not identified

Microscopic extent of tumor: Tumor invades muscularis propria.

Additional pathologic findings: None identified

AJCC Staging (7th edition): pT2 pNX pM:Not applicable

Research QC

Tumor 1:

50% tumor nuclei

0% necrosis

50% normal

this is very cauterized

T2

75% tumor nuclei

5% necrosis

20% normal

50% squamous differentiation

T3

there are 2 pieces, one is 50% tumor/50% normal; the other is entirely nonneoplastic

_% tumor nuclei

_% necrosis

_% normal

T4

30% tumor nuclei

0% necrosis

70% normal

Normal:

na

Research Specimen

Specimen Process Time

Blood draw time:

[page 2 of 2]
Plasma frozen time:
Serum frozen time:
Buffy coat frozen time:

Tissue:
Cold ischemia start time:
Formalin fixation start time:
Frozen start time:
Total cold ischemia time:
Formalin fixation stop time:
Total formalin fixation time:

Specimen Weight

Tumor x 4 - 1. 480 mg 2. 430 mg 3. 440 mg 4. 490 mg

Specimen Size

Plasma x 3
Serum x 2
Buffy coat x 1

Cryovials x 4
Normal x 0
Tumor x 4 - 1. 480 mg 2. 430 mg 3. 440 mg 4. 490 mg
Metastatic x 0

FFPE x 4
Normal x 0
Tumor x 4
Metastatic x 0

Study

Patient Consent

Yes

Diagnosis Discrepancy	/w 10/24/13	/

Source: NCI Genomic Data Commons file 1c08ab3d-8c2d-4903-a7f0-0af126c1c79c (TCGA-YC-A89H.0E633B83-3C48-4D53-B7BF-EFE0BDF73DED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).